Somatic mutation profile of tumor specimen BLGSP-71-19-00130-01A (aliquot BLGSP-71-19-00130-01A-01D-A634-33) from CGCI case BLGSP-71-19-00130, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 3.1 years (1,126 days).
Specimen BLGSP-71-19-00130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81253e78-01da-4e02-bf27-cc8551d07715.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00130-10A (Blood Derived Normal), aliquot BLGSP-71-19-00130-10A-01D-A634-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b915758-bdea-4310-950e-44cd8e138d06

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 35/237 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1672C>T p.L558F (on ENST00000399959; = p.L559F on NM_001356.5) | Missense Mutation (SNP) | VAF 128/453 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV67862997, COSV67864078; called by muse, mutect2, varscan2
- ID3 | c.300G>A p.Q100= | Splice Region (SNP) | VAF 41/96 reads (43%) | catalogued as COSV104424113, COSV65801413; called by muse, mutect2, varscan2
- MALRD1 | c.3273C>G p.S1091R | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); catalogued as COSV65988348; called by muse, mutect2, varscan2
- PRDM9 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs373299038, COSV57006680; called by muse, mutect2, varscan2
- ACSM2A | c.1376T>C p.M459T (on ENST00000219054; = p.M380T on NM_001308169.2) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
